Somatic mutation profile of tumor specimen ASCProject_0063_T2_WES (aliquot ASCProject_0063_T2_WES_1) from CMI case ASCProject_0063, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 74.4 years (27,182 days).
Specimen ASCProject_0063_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f972d0b-947f-4b4a-8e04-c7ef6dad0360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0063_SALIVA (Saliva), aliquot ASCProject_0063_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1684de7c-2b85-4b2e-ab70-bf6b5792af86

The open-access MAF lists 1,023 somatic variants for this specimen: 605 protein-altering or splice-affecting, 292 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 534, Silent 292, Intron 57, Nonsense Mutation 40, 3'UTR 24, RNA 20, Splice Site 14, 5'Flank 13, Splice Region 11, 5'UTR 11, Frame Shift Del 4, Translation Start Site 1.

Variants (750 of 1,023; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGF | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 58/386 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55949342, COSV55956077; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 88/167 reads (53%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 142/475 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777813994; called by muse, mutect2, varscan2
- ABCA8 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 254/360 reads (71%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV52214036, COSV99285400; called by muse, mutect2, varscan2
- ADAMTS5 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99537889; called by muse, mutect2, varscan2
- ADGRA3 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | catalogued as rs140443154, COSV51560801; called by muse, mutect2, varscan2
- ADGRF4 | c.1933-1G>A p.X645_splice | Splice Site (SNP) | VAF 43/236 reads (18%) | catalogued as COSV51949947, COSV51950407; called by muse, mutect2, varscan2
- ADGRL3 | c.538G>A p.G180R (on ENST00000506720 / NM_001322402.2; = p.G112R on NM_015236.6) | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268003; called by muse, mutect2, varscan2
- AGBL1 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 45/325 reads (14%) | catalogued as rs1292037752; called by muse, mutect2, varscan2
- AHI1 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1257057591, COSV55625543; called by muse, mutect2, varscan2
- AHNAK2 | c.6580G>A p.G2194R | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100317350; called by muse, mutect2, varscan2
- ALDH3A1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855964; called by muse, mutect2, varscan2
- ALK | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78086548; called by muse, mutect2, varscan2
- ALPI | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs750508053; called by muse, mutect2, varscan2
- ALPK1 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 127/244 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs1390212559; called by muse, mutect2, varscan2
- AMY2B | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.146); catalogued as COSV63715657; called by muse, mutect2, varscan2
- ANKAR | c.3799G>A p.G1267R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs755560248; called by muse, mutect2, varscan2
- ANKRD34B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775271852, COSV58613748; called by muse, mutect2, varscan2
- ANXA11 | c.-8-3C>T | Splice Region (SNP) | VAF 51/131 reads (39%) | catalogued as rs111671382; called by muse, mutect2, varscan2
- APOB | c.10049T>A p.L3350Q | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756338430; called by muse, mutect2, varscan2
- ASXL3 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs866970202; called by muse, mutect2, varscan2
- ATM | c.3335C>T p.P1112L | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs1064795850, CM0910498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRNL1 | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as COSV61804773; called by muse, mutect2, varscan2
- ATRX | c.5567-1G>C p.X1856_splice | Splice Site (SNP) | VAF 63/122 reads (52%) | catalogued as COSV64873437; called by muse, mutect2, varscan2
- B3GAT2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs750030557, COSV57644519; called by muse, mutect2, varscan2
- BCOR | c.5041C>T p.R1681C (on ENST00000378444 / NM_001123385.2; = p.R1647C on NM_017745.6) | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs768919602, COSV60702405; called by muse, mutect2, varscan2
- BEGAIN | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV62069617; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BMPR1A | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074718; called by muse, mutect2, varscan2
- BOD1L2 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1034693832; called by muse, mutect2, varscan2
- BPIFC | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200041707, COSV53277973; called by muse, mutect2, varscan2
- BPNT2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV99389327; called by muse, mutect2, varscan2
- BSX | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545151; called by muse, mutect2, varscan2
- CABIN1 | c.5842C>T p.P1948S | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.796); catalogued as COSV54079820; called by muse, mutect2, varscan2
- CCDC160 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV66251654; called by muse, mutect2, varscan2
- CD163 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs764142833; called by muse, mutect2, varscan2
- CDH15 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1156497117; called by muse, mutect2, varscan2
- CDHR4 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as rs1490437406; called by muse, mutect2, varscan2
- CFAP54 | c.5884G>A p.G1962S | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as rs11108639; called by muse, mutect2, varscan2
- CHST9 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV52445559; called by muse, mutect2, varscan2
- CLEC3A | c.439G>C p.E147Q (on ENST00000651443; = p.E138Q on NM_005752.6) | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV55222593; called by muse, mutect2, varscan2
- CLSPN | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as COSV52051957; called by muse, mutect2, varscan2
- CNGA2 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61703488; called by muse, mutect2, varscan2
- CNGA3 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 283/898 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55627790; called by muse, mutect2, varscan2
- CNGA4 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV66007325; called by muse, mutect2, varscan2
- COL15A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs1244997968, COSV66641341; called by muse, mutect2
- COL1A1 | c.3515G>A p.G1172D | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656325, CM970355; called by muse, mutect2
- COL4A3 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs781635651, CD161094, COSV67413791; called by muse, mutect2, varscan2
- CPS1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs753649832, COSV51827886; called by muse, mutect2, varscan2
- CSMD2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV53914797; called by muse, mutect2, varscan2
- CSNK2A2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs759457020; called by muse, mutect2, varscan2
- CTAGE9 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 159/794 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1160257448; called by muse, mutect2, varscan2
- DCAF12L1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV64421480; called by muse, mutect2, varscan2
- DCAF8 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as COSV58785387; called by muse, mutect2, varscan2
- DCT | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV99057983; called by muse, mutect2, varscan2
- DMBT1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1565751640, COSV57552875; called by muse, mutect2, varscan2
- DNAH11 | c.11945G>A p.G3982E | Missense Mutation (SNP) | VAF 119/414 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60977539; called by muse, mutect2, varscan2
- DNAH17 | c.7144G>A p.E2382K | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs535161506, COSV67757654; called by muse, mutect2, varscan2
- DNAH8 | c.9116C>T p.P3039L | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100547037; called by muse, mutect2
- DNMT3B | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV52421570; called by muse, mutect2, varscan2
- DPY19L2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV60541094; called by muse, mutect2, varscan2
- DRC7 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV100395428; called by muse, mutect2, varscan2
- DRICH1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV58503463; called by muse, mutect2, varscan2
- DSG2 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1463321305; called by muse, mutect2, varscan2
- DTX3 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99678267; called by muse, mutect2
- EFCC1 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1193883979; called by muse, mutect2, varscan2
- EIF4G1 | c.3904C>T p.H1302Y (on ENST00000346169 / NM_198241.3; = p.H1107Y on NM_004953.5) | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs1183546711; called by muse, mutect2, varscan2
- EPHA7 | c.2112G>A p.G704= | Splice Region (SNP) | VAF 43/170 reads (25%) | catalogued as COSV65187000; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771816182; called by muse, mutect2, varscan2
- FAM90A1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 102/1048 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56711229; called by muse, mutect2
- FANCD2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs747164592, COSV55033860; called by muse, mutect2
- FBXO40 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs372552970; called by muse, mutect2, varscan2
- FCGR1A | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1553750487; called by mutect2, varscan2
- FEM1A | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs529352942; called by muse, mutect2, varscan2
- FGFR2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 125/378 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60644402; called by muse, mutect2, varscan2
- FLT3 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV54049166, COSV54061682; called by muse, mutect2, varscan2
- FMO1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.472); catalogued as COSV61446808; called by muse, mutect2, varscan2
- FOXL2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 86/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1330762569; called by muse, mutect2, varscan2
- FOXR1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782591291; called by muse, mutect2, varscan2
- FPR2 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1271142824, COSV100389340, COSV60672598; called by muse, mutect2, varscan2
- FREM2 | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54834238; called by muse, mutect2, varscan2
- FRMD4A | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 202/646 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs781661600; called by muse, mutect2, varscan2
- GABRA2 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421381201, COSV62918278, COSV62920665; called by muse, mutect2, varscan2
- GANAB | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982101899; called by muse, mutect2, varscan2
- GBP7 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV54011546, COSV54011771; called by muse, mutect2
- GDF15 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs565768917; called by muse, mutect2, varscan2
- GJD2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1278333715, COSV51749385; called by muse, mutect2, varscan2
- GLIPR1L1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1161016551; called by muse, mutect2
- GPR179 | c.3386G>A p.R1129Q (on ENST00000621958; = p.R1128Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs370214602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRC5B | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as rs767265211; called by muse, mutect2
- GPRC5B | c.1170C>T p.I390= | Splice Region (SNP) | VAF 16/210 reads (8%) | catalogued as COSV56028045; called by muse, mutect2
- GREB1 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52185984, COSV99302768; called by muse, mutect2, varscan2
- GREB1L | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs545786663; called by muse, mutect2, varscan2
- HGF | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55959610; called by muse, mutect2, varscan2
- HMGB4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs868581855; called by muse, mutect2, varscan2
- HNRNPL | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370003343; called by muse, mutect2, varscan2
- HOOK1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409731587; called by muse, mutect2, varscan2
- HOXD12 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV66832966; called by muse, mutect2, varscan2
- HR | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57192741; called by muse, mutect2, varscan2
- HYDIN | c.7651G>A p.E2551K | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1309595027, COSV59255455; called by muse, mutect2, varscan2
- IGHA1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs759163072; called by muse, mutect2, varscan2
- IGKV1-5 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs532276861; called by muse, mutect2, varscan2
- IL1RL1 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52115509; called by muse, mutect2, varscan2
- IL34 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as rs369011177; called by muse, mutect2, varscan2
- ITGB2 | c.1156-5C>T | Splice Region (SNP) | VAF 143/727 reads (20%) | catalogued as rs781696813; called by muse, mutect2, varscan2
- KCMF1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69053984; called by muse, mutect2, varscan2
- KCNA10 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63904164; called by muse, mutect2, varscan2
- KCNF1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1366655124; called by muse, mutect2, varscan2
- KCNF1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54465332; called by muse, mutect2, varscan2
- KCNH8 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs867874775; called by muse, mutect2, varscan2
- KCNQ5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571764; called by muse, mutect2, varscan2
- KIAA2012 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs747893606; called by muse, mutect2, varscan2
- KLHL33 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV60726181; called by muse, mutect2, varscan2
- KLK8 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1223589391, COSV51591724; called by muse, mutect2, varscan2
- KMT2D | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.065); catalogued as rs769731886; called by muse, mutect2, varscan2
- KRTAP10-5 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 71/503 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59967602; called by muse, mutect2, varscan2
- KRTAP5-4 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as rs1375009958, COSV101294467; called by muse, varscan2
- LAIR1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57309556; called by muse, mutect2, varscan2
- LAMA1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779998352; called by muse, mutect2, varscan2
- LAMB3 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 183/614 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV61916797; called by muse, mutect2, varscan2
- LHCGR | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs763876123, COSV54296173; called by muse, mutect2, varscan2
- LHCGR | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs944199288, COSV54291962; called by muse, mutect2, varscan2
- LIPF | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53282675, COSV53283304; called by muse, mutect2
- LRP1B | c.11962C>T p.H3988Y | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.954); catalogued as COSV67218311; called by muse, mutect2, varscan2
- LRP2 | c.12053C>T p.P4018L | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55548702; called by muse, mutect2, varscan2
- LRRIQ3 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV63042045, COSV63042170; called by muse, mutect2
- MACF1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 280/867 reads (32%) | catalogued as rs1413066604, COSV58363735; called by muse, mutect2, varscan2
- MAGEE2 | c.1446G>T p.E482D | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64897225; called by muse, mutect2, varscan2
- MAS1L | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs1199489913, COSV65808390; called by muse, mutect2, varscan2
- MECOM | c.2743G>A p.E915K (on ENST00000468789 / NM_001105078.4; = p.E1103K on NM_004991.4) | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV52977561; called by muse, mutect2, varscan2
- MFSD10 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1297851840; called by muse, mutect2, varscan2
- MGAM | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71886194; called by muse, mutect2, varscan2
- MGAM | c.4708C>T p.R1570C | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601326, COSV72074844; called by muse, mutect2, varscan2
- MGAT5B | c.1606C>T p.P536S (on ENST00000569840 / NM_001199172.2; = p.P534S on NM_144677.3) | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV56936440, COSV56937598; called by muse, mutect2
- MMP1 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV59511147; called by muse, mutect2, varscan2
- MMP12 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs868954103, COSV58261759; called by muse, mutect2, varscan2
- MOCOS | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as rs750931852, COSV54343262; called by muse, mutect2, varscan2
- MOCOS | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV99732836; called by muse, mutect2, varscan2
- MROH7 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866660481; called by muse, mutect2, varscan2
- MSLN | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.025); catalogued as rs747128206, COSV99558578; called by muse, mutect2, varscan2
- MTHFD1L | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1422023663; called by muse, mutect2, varscan2
- MTUS2 | c.3653G>A p.R1218K (on ENST00000612955 / NM_001366650.1; = p.R197K on NM_015233.6) | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.876); catalogued as rs1276054436; called by muse, mutect2, varscan2
- MUC16 | c.25277G>A p.R8426K | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.028); catalogued as COSV67467884; called by muse, mutect2, varscan2
- MUC16 | c.24803C>T p.S8268F | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1330676451, COSV67461695; called by muse, mutect2, varscan2
- MUC16 | c.17701G>A p.E5901K | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as rs760021920; called by muse, mutect2, varscan2
- MUC16 | c.17269G>A p.D5757N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.917); catalogued as rs910009324, COSV67477126; called by muse, mutect2, varscan2
- MYC | c.130G>A p.A44T (on ENST00000377970; = p.A59T on NM_002467.6) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52371326; called by muse, mutect2, varscan2
- MYH14 | c.4972G>A p.E1658K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs774603941, COSV51835645; called by muse, mutect2, varscan2
- MYH8 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101238154; called by muse, mutect2, varscan2
- MYLK2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV65659588; called by muse, mutect2, varscan2
- MYOG | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs889680630, COSV54095723; called by muse, mutect2, varscan2
- NBEA | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1190989650, COSV59763269; called by muse, mutect2, varscan2
- NBEA | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | catalogued as rs1296627050, COSV59785071; called by muse, mutect2
- NCKAP5 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs758470126, COSV58443225; called by muse, mutect2, varscan2
- NEUROD1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV99716769; called by muse, mutect2, varscan2
- NHLRC4 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV50312904; called by muse, mutect2, varscan2
- NLRP13 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61622513; called by muse, mutect2, varscan2
- NOD2 | c.1618C>T p.L540F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.344); catalogued as COSV56049549, COSV56052749; called by muse, mutect2, varscan2
- NOS3 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.314); catalogued as COSV52486851; called by muse, mutect2, varscan2
- NOX1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV54193974; called by muse, mutect2, varscan2
- NRXN2 | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as rs1226709495; called by muse, mutect2, varscan2
- NSD2 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100373226; called by muse, mutect2
- NTRK2 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 93/543 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52877456; called by muse, mutect2, varscan2
- NYAP2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55999264; called by muse, mutect2, varscan2
- OBSCN | c.6688G>C p.A2230P | Missense Mutation (SNP) | VAF 65/439 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); catalogued as COSV52759548; called by muse, mutect2, varscan2
- OR13C3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1490021198; called by muse, mutect2, varscan2
- OR2A12 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV68821794; called by muse, mutect2, varscan2
- OR2L2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63549398, COSV63559425; called by muse, mutect2, varscan2
- OR2T27 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV61281368; called by muse, mutect2
- OR4A5 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV60521730, COSV60523084; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2
- OR51L1 | c.715G>C p.A239P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58624087; called by muse, mutect2, varscan2
- OR51V1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315278; called by muse, mutect2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OR6K6 | c.284C>T p.S95F (on ENST00000368144; = p.S71F on NM_001005184.1) | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63743789; called by muse, mutect2, varscan2
- OSBPL3 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1344048282; called by muse, mutect2, varscan2
- PACS2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs781934467; called by muse, mutect2
- PALM | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs1292986648; called by muse, mutect2, varscan2
- PAMR1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs778036197, COSV53511941; called by muse, varscan2
- PANX3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.656); catalogued as rs761067273; called by muse, mutect2
- PAX8 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as rs1275690866; called by muse, mutect2, varscan2
- PCDH15 | c.4555G>A p.E1519K (on ENST00000644397 / NM_001354429.2; = p.M1479I on NM_001142770.3) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.376); catalogued as rs769524004, COSV64750080; called by muse, mutect2, varscan2
- PCOLCE2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.067); catalogued as rs761462363, COSV55997270; called by muse, mutect2, varscan2
- PDZD2 | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV56873226; called by muse, mutect2
- PEX2 | c.-160G>A | Splice Region (SNP) | VAF 97/312 reads (31%) | catalogued as rs1319512534, COSV63814111; called by muse, mutect2, varscan2
- PIK3CG | c.1250G>C p.S417T | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV63255028; called by muse, mutect2, varscan2
- PKHD1 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV61882934; called by muse, mutect2, varscan2
- PKLR | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 158/554 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361195; called by muse, mutect2, varscan2
- PLK5 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 23/181 reads (13%) | catalogued as rs1480456586; called by muse, mutect2, varscan2
- POLR3A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as rs772321979; called by muse, mutect2, varscan2
- POTEC | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1333590088, COSV62800938; called by muse, mutect2, varscan2
- PRAMEF2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs553285373, COSV53574458; called by muse, mutect2, varscan2
- PRKCB | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57783292, COSV57806070; called by muse, mutect2, varscan2
- PTGFR | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs754322857; called by mutect2, varscan2
- PTK2B | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV100593401; called by muse, mutect2
- PTPRD | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61960983; called by muse, mutect2, varscan2
- PUDP | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs3747386; called by muse, mutect2, varscan2
- PXDNL | c.4045G>A p.D1349N | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62488030; called by muse, mutect2, varscan2
- QSOX2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs772753193; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs994065028, COSV99424851; called by muse, mutect2, varscan2
- RGS22 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV62659684; called by muse, mutect2, varscan2
- RGS22 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100693217; called by muse, mutect2, varscan2
- RHPN2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1568318216, COSV99577132; called by muse, mutect2, varscan2
- RIMBP2 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55474686; called by muse, mutect2, varscan2
- RIMS2 | c.2471G>A p.R824Q (on ENST00000666250 / NM_001348490.2; = p.R632Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); catalogued as rs868696973, COSV51702871; called by muse, mutect2, varscan2
- RIMS2 | c.3548-1G>A p.X1183_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as COSV51672175, COSV99165552; called by muse, mutect2
- RP1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV55111256; called by muse, mutect2, varscan2
- RRP12 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV59671975; called by muse, mutect2, varscan2
- RYR3 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567641089, COSV101212766; called by muse, mutect2, varscan2
- SCN1A | c.2672G>A p.G891E (on ENST00000303395 / NM_001202435.3; = p.G880E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868742933, COSV57662402; called by muse, mutect2
- SEL1L3 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV53550760; called by muse, mutect2, varscan2
- SERPINA4 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV54069460, COSV54071336; called by muse, mutect2
- SERPINB10 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374892728; called by muse, mutect2, varscan2
- SETBP1 | c.4012C>T p.P1338S | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV56322714; called by muse, mutect2, varscan2
- SF3B2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as rs1293270452; called by muse, mutect2, varscan2
- SGPP2 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1019559091; called by muse, mutect2, varscan2
- SH3BP5L | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs538525157; called by muse, mutect2
- SH3RF2 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 62/493 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs762782467, COSV63039028; called by muse, mutect2, varscan2
- SLC1A2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866322265; called by muse, varscan2
- SLC22A2 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 67/315 reads (21%) | catalogued as rs896799392, COSV65267463; called by muse, mutect2, varscan2
- SLC22A6 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs1399219233, COSV64559899; called by muse, mutect2, varscan2
- SLC44A3 | c.380C>T p.S127F (on ENST00000271227 / NM_001114106.3; = p.S79F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV54734237; called by muse, mutect2, varscan2
- SLC6A16 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60028497; called by muse, mutect2, varscan2
- SLCO1A2 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56603549; called by muse, mutect2
- SLCO5A1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 47/432 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs201712813; called by muse, mutect2, varscan2
- SMIM2 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs950584196; called by muse, mutect2, varscan2
- SORBS1 | c.3757C>T p.R1253C (on ENST00000361941 / NM_001034954.2; = p.R645C on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs753211607; called by muse, mutect2, varscan2
- SORL1 | c.5234G>A p.G1745E | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV52752209, COSV99495688; called by muse, mutect2, varscan2
- SPATA31A6 | c.1214A>C p.Q405P | Missense Mutation (SNP) | VAF 138/251 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV60535429; called by muse, mutect2, varscan2
- SPRR2D | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 136/531 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1001513669, COSV64209229; called by muse, mutect2, varscan2
- SPTA1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV63753714; called by muse, varscan2
- STEAP4 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs754509742, COSV57328108; called by muse, mutect2, varscan2
- SYT14 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.931); catalogued as rs1219189034; called by muse, mutect2, varscan2
- TAF6L | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV99585407; called by muse, mutect2, varscan2
- TDGF1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 117/634 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs146889320; called by muse, mutect2, varscan2
- TMEM151A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs767721223; called by muse, mutect2, varscan2
- TNN | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375173557; called by muse, mutect2, varscan2
- TRAF3IP1 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375052092; called by muse, mutect2
- TRIM6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53479678; called by muse, mutect2, varscan2
- TRPM4 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs758422000, COSV53264153; called by muse, varscan2
- TSPAN18 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs372441531; called by muse, mutect2, varscan2
- TTLL4 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51439933; called by muse, mutect2, varscan2
- TTLL6 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 103/945 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs771576064, COSV104428331; called by muse, mutect2, varscan2
- TUBA4B | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1479778757; called by muse, mutect2, varscan2
- UBD | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs779055798; called by muse, mutect2, varscan2
- UBE2U | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs754709262; called by muse, mutect2
- UBE2U | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 22/188 reads (12%) | catalogued as COSV64281635; called by muse, mutect2
- UGT3A1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV57104374; called by muse, mutect2, varscan2
- WDR72 | c.3301G>A p.V1101M | Missense Mutation (SNP) | VAF 71/537 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs748454326; called by muse, mutect2, varscan2
- WDR87 | c.6817G>A p.E2273K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.638); catalogued as COSV58197324; called by muse, mutect2
- WNT10A | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs1351117506; called by muse, mutect2, varscan2
- XIRP1 | c.4350G>A p.M1450I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1425585082, COSV61139415; called by muse, mutect2
- XIRP1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs774826792; called by muse, mutect2, varscan2
- XIRP2 | c.7495G>A p.E2499K (on ENST00000628543; = p.E2674K on NM_152381.6) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as rs768719822, COSV54690550; called by muse, mutect2, varscan2
- ZFAT | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748138009, COSV64743111; called by muse, mutect2
- ZFYVE28 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as rs988422580, COSV99343053; called by muse, mutect2, varscan2
- ZNF257 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1568492801, COSV71306477; called by muse, mutect2
- ZNF585B | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | catalogued as COSV57216339; called by muse, mutect2, varscan2
- ZNF610 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs149251185; called by muse, mutect2, varscan2
- ZNF679 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1400448923, COSV55378276; called by muse, mutect2, varscan2
- ZNF735 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV70036128; called by muse, mutect2, varscan2
- ZNF786 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370130047, COSV60276858; called by muse, mutect2, varscan2
- ZSCAN23 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as COSV99231732; called by muse, mutect2, varscan2
- AADACL2 | c.432-2A>T p.X144_splice | Splice Site (SNP) | VAF 80/257 reads (31%) | called by muse, mutect2, varscan2
- AADACL2 | c.432-1G>A p.X144_splice | Splice Site (SNP) | VAF 82/264 reads (31%) | called by muse, mutect2, varscan2
- AATK | c.706G>A p.E236K (on ENST00000326724 / NM_001080395.3; = p.E133K on NM_004920.2) | Missense Mutation (SNP) | VAF 116/265 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABCA13 | c.7433T>A p.L2478* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ABCA13 | c.11205G>A p.G3735= | Splice Region (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- ABCA5 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 21/459 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- ABCA6 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.392T>G p.L131W | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- AC004593.2 | c.1136G>A p.R379K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ACAN | c.5497G>A p.D1833N | Missense Mutation (SNP) | VAF 220/578 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG2 | c.1663A>C p.M555L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACTA2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 183/472 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ACTRT1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ADAMTS3 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS7 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 119/336 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ADGRF3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL3 | c.539G>A p.G180E (on ENST00000506720 / NM_001322402.2; = p.G112E on NM_015236.6) | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF2 | c.979A>T p.K327* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- AGAP3 | c.1493C>T p.S498F (on ENST00000622464; = p.S534F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- AHNAK2 | c.13259C>T p.P4420L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK5 | c.505A>G p.K169E (on ENST00000354567 / NM_174858.3; = p.K143E on NM_012093.4) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.137); called by muse, mutect2
- AKR1D1 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, varscan2
- ALDH16A1 | c.760-5C>T | Splice Region (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- ALX3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.188); called by muse, varscan2
- AMER2 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.12322C>A p.L4108M (on ENST00000280772 / NM_001320874.2; = p.L629M on NM_001149.3) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD30A | c.2929C>T p.L977F (on ENST00000611781; = p.L921F on NM_052997.2) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD34B | c.1437_1438del p.L480Yfs*9 | Frame Shift Del (DEL) | VAF 60/318 reads (19%) | called by mutect2, pindel, varscan2
- AP002495.1 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- APOB | c.7661G>A p.W2554* | Nonsense Mutation (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- AR | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF3 | c.4139C>T p.P1380L | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGAP20 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ARHGAP31 | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 186/626 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ARHGAP42 | c.463A>T p.K155* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- ARID1B | c.5396_5411del p.F1799Cfs*34 | Frame Shift Del (DEL) | VAF 76/380 reads (20%) | called by mutect2, pindel, varscan2
- ARL6 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ARSG | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 273/394 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARSL | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- ART3 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ASXL1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 41/229 reads (18%) | called by muse, mutect2, varscan2
- ATF7IP | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG14 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ATG16L1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- BCAN | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- BCKDK | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- C4B | c.3783G>A p.W1261* | Nonsense Mutation (SNP) | VAF 60/332 reads (18%) | called by mutect2, varscan2
- C5orf47 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C9orf135 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CACNA1F | c.5866G>A p.E1956K | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CACNG3 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CADM1 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CADM3 | c.902C>A p.A301D (on ENST00000368125 / NM_001127173.3; = p.A335D on NM_021189.5) | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS2 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CALN1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD14 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2
- CARMIL3 | c.1062+2T>A p.X354_splice | Splice Site (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- CCDC190 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 33/326 reads (10%) | called by muse, mutect2, varscan2
- CCDC22 | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC38 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CCDC54 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCSAP | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2
- CD163 | c.2641G>A p.D881N | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDC14C | c.547A>C p.K183Q (on ENST00000428251; = p.K76Q on NM_152627.3) | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDH12 | c.640A>T p.K214* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- CEACAM18 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, varscan2
- CELSR2 | c.6500T>A p.I2167N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CELSR3 | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CFAP43 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP45 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CFAP46 | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CFD | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CLDN16 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CLEC4C | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- CLEC5A | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CMYA5 | c.3979G>T p.V1327F | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- COL22A1 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL4A3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.3214A>T p.T1072S | Missense Mutation (SNP) | VAF 57/330 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CRYBG2 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CSTF2 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CTSO | c.698A>T p.K233I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CWH43 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CYP27B1 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCDC1 | c.2264G>A p.W755* | Nonsense Mutation (SNP) | VAF 49/208 reads (24%) | called by muse, mutect2, varscan2
- DCSTAMP | c.1338+1G>T p.X446_splice | Splice Site (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- DDIAS | c.773T>G p.F258C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- DDR2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DENND1C | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- DNAH5 | c.12868C>T p.P4290S | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DNAH5 | c.4740A>T p.E1580D | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- DNHD1 | c.9655G>A p.A3219T | Missense Mutation (SNP) | VAF 158/528 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DOCK5 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DRD3 | c.411C>G p.H137Q | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSG3 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- EDIL3 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EEF1A2 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EFCAB5 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ELFN1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- EML1 | c.2008-4C>T | Splice Region (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- ENPP2 | c.982C>T p.P328S (on ENST00000075322 / NM_001040092.3; = p.P380S on NM_006209.5) | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EPHA4 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EPN3 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 63/748 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.054); called by muse, mutect2
- EPOR | c.968T>G p.F323C | Missense Mutation (SNP) | VAF 80/549 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ERBB3 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 39/346 reads (11%) | called by muse, mutect2, varscan2
- ERBB3 | c.2876A>T p.K959I | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM111B | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM135B | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FAM181A | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FBF1 | c.2882A>G p.E961G (on ENST00000586717; = p.E976G on NM_001319193.1) | Missense Mutation (SNP) | VAF 19/532 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- FIP1L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FKTN | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FOXN1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- FRMPD4 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FRY | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- GDA | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLIS1 | c.1071G>T p.L357= | Splice Region (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- GOLGA4 | c.5582C>T p.S1861F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, varscan2
- GPR65 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- GRIK2 | c.901T>A p.L301M | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- GRIN2A | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.4262T>C p.F1421S | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- GRM5 | c.632G>A p.W211* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- GTDC1 | c.897A>C p.E299D | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- H1-4 | c.165C>G p.S55R | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- HAO2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- HK2 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 79/477 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOMER2 | c.722G>A p.R241K (on ENST00000304231 / NM_199330.3; = p.R230K on NM_004839.4) | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRG | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- HSD11B1 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGBP1P2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGDCC3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 142/437 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- IGSF1 | c.2380_2381insT p.R794Lfs*23 | Frame Shift Ins (INS) | VAF 41/71 reads (58%) | called by mutect2, pindel*, varscan2*
- IGSF9B | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); called by muse, mutect2
- IL12RB2 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 62/482 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL1RAP | c.1649A>T p.K550I | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- IL1RAP | c.1650A>T p.K550N | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ILVBL | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INO80E | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- IRX1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- ITIH6 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, varscan2
- IVL | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 83/367 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- JAKMIP3 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- JMJD4 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KCNA4 | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1109 | c.12896C>T p.S4299F | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA1755 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF5C | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIR2DS4 | c.184A>T p.R62* | Nonsense Mutation (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.643-1G>A p.X215_splice | Splice Site (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- KIR2DS4 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2
- KIR3DL3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2
- KRR1 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KRT2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT82 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 113/394 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KRT84 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- KSR2 | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 187/559 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCK | c.-5-6C>T | Splice Region (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
- LHX5 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA6 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LINGO4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- LONP1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 201/733 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN1 | c.1697_1706del p.D566Afs*119 | Frame Shift Del (DEL) | VAF 25/190 reads (13%) | called by mutect2, pindel
- LRP2 | c.12832G>A p.D4278N | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRPPRC | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 83/313 reads (27%) | called by muse, mutect2, varscan2
- LRRC2 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- LRRC42 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LTBP3 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAGEB2 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 106/190 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAN1A1 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2
- MAP10 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAPK8IP1 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 80/599 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MAPK8IP3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 75/587 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST1 | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MCOLN2 | c.1461del p.L487Ffs*11 | Frame Shift Del (DEL) | VAF 45/266 reads (17%) | called by pindel, varscan2
- MOK | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MPP6 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MRC2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 148/218 reads (68%) | called by muse, mutect2, varscan2
- MROH1 | c.3868G>A p.G1290R | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MROH1 | c.4642G>A p.E1548K | Missense Mutation (SNP) | VAF 60/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MROH2A | c.2836G>A p.G946R | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MROH7 | c.3410C>T p.T1137I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MTMR8 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MTMR9 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MUC16 | c.16964C>T p.S5655F | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC16 | c.2857A>T p.R953* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | called by muse, varscan2
- MUC17 | c.6484C>T p.P2162S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2
- MUC17 | c.7178G>A p.S2393N | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MUC22 | c.2693T>G p.V898G | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC5B | c.9641C>T p.S3214F | Missense Mutation (SNP) | VAF 147/522 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MUC5B | c.12139G>A p.G4047R | Missense Mutation (SNP) | VAF 54/806 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- MVB12B | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- MX1 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- MYBL2 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH14 | c.3997C>T p.Q1333* | Nonsense Mutation (SNP) | VAF 77/296 reads (26%) | called by muse, mutect2, varscan2
- MYO18B | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MYRIP | c.1472A>G p.H491R | Missense Mutation (SNP) | VAF 272/595 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NAIP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2
- NAV2 | c.6262G>A p.G2088R (on ENST00000396087 / NM_001244963.2; = p.G2029R on NM_145117.5) | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.18927C>G p.Y6309* | Nonsense Mutation (SNP) | VAF 44/225 reads (20%) | called by muse, mutect2, varscan2
- NKAIN2 | c.245T>G p.F82C | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOTUM | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2
- NOVA2 | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 261/806 reads (32%) | called by muse, mutect2, varscan2
- NR1I3 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); called by muse, mutect2
- NR2E1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 206/573 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NRXN1 | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN2 | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP205 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- OR2S2 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OR51Q1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR5M1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR8B4 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PADI1 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PANK1 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANK4 | c.1908T>A p.F636L | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PANX2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PASK | c.3243G>A p.M1081I | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAX2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 117/355 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH11X | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PCDHA6 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA8 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 105/815 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PCDHAC2 | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PCDHGA7 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2, varscan2
- PDE1A | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE6C | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE6C | c.2518+1G>A p.X840_splice | Splice Site (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- PDXDC1 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PDZRN4 | c.1918C>T p.H640Y (on ENST00000402685 / NM_001164595.2; = p.H382Y on NM_013377.4) | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PGAP1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHRF1 | c.2554C>T p.P852S (on ENST00000264555 / NM_001286581.2; = p.P851S on NM_020901.4) | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3AP1 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PITPNM2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.12419G>A p.G4140E | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2
- PKLR | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 160/553 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHH1 | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLXND1 | c.5102A>G p.E1701G | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PML | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PMVK | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- POLE | c.6298C>T p.P2100S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- POM121L2 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- POTEJ | c.2346G>T p.M782I | Missense Mutation (SNP) | VAF 116/463 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PPFIA2 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPM1E | c.1160G>T p.W387L | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2
- PRAMEF17 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PRAMEF17 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PRDM7 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKCB | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 16/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRR19 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSKH2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PTPRZ1 | c.4141C>T p.P1381S | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- QSOX2 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- QSOX2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- RAB6C | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2
- RAD51AP2 | c.2084A>C p.D695A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RAD51AP2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- RAP1GAP | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RASGRP3 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- RFPL4A | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, varscan2
- RHCG | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RHD | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 137/229 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- RIPK4 | c.1688G>A p.G563E (on ENST00000352483; = p.G515E on NM_020639.3) | Missense Mutation (SNP) | VAF 98/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEH2C | c.349-4C>T | Splice Region (SNP) | VAF 242/730 reads (33%) | called by muse, mutect2, varscan2
- RNF17 | c.2944G>A p.G982S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- RSPH6A | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.10474G>A p.E3492K | Missense Mutation (SNP) | VAF 54/538 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); called by muse, mutect2
- RYR2 | c.6539G>A p.G2180E | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SACS | c.9656C>T p.S3219F | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SALL1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SARDH | c.2490G>A p.M830I | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SCUBE2 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK2 | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 325/463 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETDB2 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFTPA2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 95/582 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SHLD2P1 | n.2016+1G>A | Splice Site (SNP) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- SHROOM2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHROOM4 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIK3 | c.3978T>G p.S1326R (on ENST00000445177 / NM_001366686.2; = p.S1284R on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SLAMF1 | c.372A>T p.K124N | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- SLC22A6 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC24A2 | c.1129+1G>T p.X377_splice | Splice Site (SNP) | VAF 19/157 reads (12%) | called by muse, varscan2
- SLC30A10 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35C2 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 42/291 reads (14%) | called by muse, mutect2, varscan2
- SLC35G2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SLC5A5 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SLCO1A2 | c.1734G>A p.W578* | Nonsense Mutation (SNP) | VAF 21/251 reads (8%) | called by muse, mutect2
- SLCO4C1 | c.2108A>G p.K703R | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA4 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SMG9 | c.189A>T p.K63N | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SMIM14 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SOS2 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- SPHK2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPTBN4 | c.7493+1G>A p.X2498_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- SSU72P8 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SSX7 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- SSX7 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STPG4 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SVEP1 | c.1277G>A p.W426* | Nonsense Mutation (SNP) | VAF 74/373 reads (20%) | called by muse, mutect2, varscan2
- TDRD15 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TDRD6 | c.1855T>G p.F619V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TECTB | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TERF1 | c.1303T>G p.S435A (on ENST00000276603 / NM_017489.3; = p.S415A on NM_003218.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TFR2 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM132A | c.2174G>A p.G725E (on ENST00000453848 / NM_178031.3; = p.G726E on NM_017870.4) | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TMEM132C | c.379T>A p.F127I | Missense Mutation (SNP) | VAF 153/506 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TMPRSS2 | c.1130A>C p.Q377P | Missense Mutation (SNP) | VAF 139/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TPO | c.2156A>C p.E719A | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAPPC8 | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- TRAV1-1 | c.139T>G p.Y47D | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRBV29-1 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TREM1 | c.81A>T p.E27D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2
- TRIM39 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 128/385 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM51 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 63/700 reads (9%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.4545C>A p.S1515R | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TSSC4 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TTC25 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TUBA4B | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYRO3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TYRP1 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- UBALD2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 25/745 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- UGT1A10 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UNC5C | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- UQCRQ | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- UVRAG | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- VNN2 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13A | c.7786C>T p.Q2596* | Nonsense Mutation (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- VPS13D | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- VWCE | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- WDFY4 | c.4757G>A p.G1586E | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- WDR27 | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- XIRP2 | c.5566G>A p.D1856N (on ENST00000628543; = p.D2031N on NM_152381.6) | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF100 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ZNF14 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF404 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF581 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF676 | c.91A>C p.N31H | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF747 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF784 | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); called by muse, varscan2
- ZNF831 | c.4358C>T p.S1453F | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNRF1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZZEF1 | c.5096A>G p.D1699G | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ABCA4 | c.6519C>T p.S2173= | Silent (SNP) | VAF 136/422 reads (32%) | catalogued as rs1557757728; called by muse, mutect2, varscan2
- ABCA4 | c.6195C>T p.D2065= | Silent (SNP) | VAF 100/715 reads (14%) | called by muse, mutect2, varscan2
- ABCC4 | c.1338C>T p.P446= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs759409909, COSV65315500; called by muse, mutect2, varscan2
- AC127029.3 | c.435C>T p.D145= | Silent (SNP) | VAF 86/1112 reads (8%) | catalogued as rs577521176; called by muse, mutect2
- ACTA1 | c.99C>T p.F33= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as rs774698359; called by muse, mutect2, varscan2
- ADAL | c.90C>T p.S30= | Silent (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.546C>T p.P182= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs369900757; called by muse, mutect2, varscan2
- ADGRD1 | c.1875C>T p.L625= | Silent (SNP) | VAF 68/324 reads (21%) | catalogued as rs771181899, COSV55455063; called by muse, mutect2, varscan2
- ADGRF5 | c.2742G>A p.Q914= | Silent (SNP) | VAF 53/199 reads (27%) | catalogued as rs1281676003; called by muse, mutect2, varscan2
- ADGRG3 | c.1533C>T p.S511= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs777488471, COSV59651388; called by muse, mutect2, varscan2
- ALPG | c.1566C>T p.T522= | Silent (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- ALX3 | c.342C>T p.P114= | Silent (SNP) | VAF 38/120 reads (32%) | called by muse, varscan2
- AMFR | c.564C>T p.S188= | Silent (SNP) | VAF 52/393 reads (13%) | catalogued as rs1490110420; called by muse, mutect2, varscan2
- ANKFN1 | c.1716C>T p.S572= | Silent (SNP) | VAF 26/373 reads (7%) | catalogued as COSV59445709; called by muse, mutect2
- ANO1 | c.2778G>A p.E926= | Silent (SNP) | VAF 129/535 reads (24%) | catalogued as rs759383865, COSV100796937; called by muse, mutect2, varscan2
- ANO7 | c.360G>C p.L120= (on ENST00000274979; = p.L65= on NM_001001666.4) | Silent (SNP) | VAF 134/325 reads (41%) | called by muse, mutect2, varscan2
- ANXA2 | c.972G>A p.K324= | Silent (SNP) | VAF 121/416 reads (29%) | catalogued as rs964350786, COSV100222073; called by muse, mutect2, varscan2
- APC2 | c.5601C>T p.R1867= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs748671970; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASH1L | c.1980C>T p.S660= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- ASTN1 | c.142C>T p.L48= | Silent (SNP) | VAF 62/487 reads (13%) | catalogued as rs1558142692; called by muse, mutect2, varscan2
- ASTN2 | c.1944C>T p.S648= (on ENST00000313400 / NM_001365069.1; = p.S597= on NM_014010.5) | Silent (SNP) | VAF 44/236 reads (19%) | catalogued as rs777087582, COSV57815371; called by muse, mutect2, varscan2
- ATP2B1 | c.3108T>A p.L1036= | Silent (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- ATP6V1E2 | c.144C>T p.T48= | Silent (SNP) | VAF 28/250 reads (11%) | catalogued as COSV60575672; called by muse, mutect2, varscan2
- AXL | c.1050C>T p.F350= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as rs1438536181, COSV56565671; called by muse, mutect2, varscan2
- BASP1 | c.354G>A p.E118= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- BCL7C | c.708C>T p.I236= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- BIN1 | c.1101C>T p.V367= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- BSN | c.756C>T p.S252= | Silent (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- BSX | c.408C>G p.S136= | Silent (SNP) | VAF 87/198 reads (44%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.360G>A p.G120= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- CACNA1G | c.3342C>T p.G1114= | Silent (SNP) | VAF 200/404 reads (50%) | called by muse, mutect2, varscan2
- CADM1 | c.180G>A p.A60= | Silent (SNP) | VAF 55/348 reads (16%) | catalogued as rs140607939; called by muse, mutect2, varscan2
- CAPN10 | c.1242C>A p.G414= | Silent (SNP) | VAF 57/257 reads (22%) | called by muse, mutect2, varscan2
- CAPN6 | c.679C>T p.L227= | Silent (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2
- CARD14 | c.201C>T p.A67= | Silent (SNP) | VAF 43/206 reads (21%) | called by muse, mutect2, varscan2
- CCDC116 | c.1101C>T p.R367= | Silent (SNP) | VAF 84/188 reads (45%) | catalogued as COSV53040432; called by muse, mutect2, varscan2
- CCDC180 | c.792C>T p.A264= | Silent (SNP) | VAF 70/193 reads (36%) | called by muse, mutect2, varscan2
- CCDC68 | c.975C>T p.S325= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as rs1245600340; called by muse, varscan2
- CD163 | c.2880G>A p.L960= | Silent (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- CDH1 | c.1014C>T p.F338= | Silent (SNP) | VAF 133/447 reads (30%) | catalogued as rs777441715; called by muse, mutect2, varscan2
- CDHR4 | c.1500G>A p.L500= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- CDR2L | c.648G>A p.A216= | Silent (SNP) | VAF 22/412 reads (5%) | catalogued as rs1485416374; called by muse, mutect2
- CEACAM18 | c.447G>A p.V149= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV67282596; called by muse, varscan2
- CEP164 | c.1452C>T p.P484= | Silent (SNP) | VAF 97/310 reads (31%) | catalogued as rs373736623, COSV99633798; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP72 | c.1533G>A p.K511= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV53791800; called by muse, mutect2, varscan2
- CFTR | c.609C>T p.I203= | Silent (SNP) | VAF 54/583 reads (9%) | catalogued as rs1800081, CM043462, COSV50073612; called by muse, mutect2
- CGA | c.204G>A p.K68= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs142907318, COSV100851678, COSV63644449; called by muse, mutect2, varscan2
- CHD5 | c.1701G>A p.K567= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV52411734; called by muse, mutect2, varscan2
- CHRNA4 | c.267G>A p.V89= | Silent (SNP) | VAF 68/391 reads (17%) | called by muse, mutect2, varscan2
- CLDN16 | c.606C>T p.S202= | Silent (SNP) | VAF 80/321 reads (25%) | catalogued as COSV99290129; called by muse, mutect2, varscan2
- COIL | c.813C>A p.S271= | Silent (SNP) | VAF 36/334 reads (11%) | called by muse, mutect2, varscan2
- COL4A4 | c.234C>A p.P78= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV100307021; called by muse, mutect2, varscan2
- COL7A1 | c.585C>T p.F195= | Silent (SNP) | VAF 110/249 reads (44%) | called by muse, mutect2, varscan2
- COL9A2 | c.672C>T p.I224= | Silent (SNP) | VAF 122/449 reads (27%) | called by muse, mutect2, varscan2
- COMMD8 | c.9G>A p.P3= | Silent (SNP) | VAF 65/214 reads (30%) | catalogued as COSV104431195; called by muse, mutect2, varscan2
- CPAMD8 | c.1686C>T p.A562= (on ENST00000651564; = p.A515= on NM_015692.5) | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as COSV99359449; called by muse, mutect2
- CPEB1 | c.483C>T p.S161= (on ENST00000617958; = p.S101= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/356 reads (10%) | catalogued as COSV55621522; called by muse, mutect2, varscan2
- CPED1 | c.2488T>C p.L830= | Silent (SNP) | VAF 85/267 reads (32%) | catalogued as rs1271984269; called by muse, mutect2, varscan2
- CPED1 | c.2541C>T p.P847= | Silent (SNP) | VAF 34/241 reads (14%) | catalogued as COSV100120717; called by muse, mutect2, varscan2
- CPPED1 | c.282C>T p.A94= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs370714292; called by muse, mutect2, varscan2
- CSPP1 | c.426C>T p.S142= (on ENST00000676605; = p.S101= on NM_024790.6) | Silent (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- CYP2A13 | c.960C>T p.H320= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- CYP2C19 | c.1395G>A p.K465= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as COSV100990629, COSV64908681; called by muse, mutect2, varscan2
- DCAF4 | c.1290G>A p.V430= | Silent (SNP) | VAF 13/284 reads (5%) | catalogued as COSV100610934; called by muse, mutect2
- DCDC1 | c.828G>A p.R276= | Silent (SNP) | VAF 65/248 reads (26%) | catalogued as COSV100662835, COSV60849750; called by muse, mutect2, varscan2
- DDIT4L | c.231G>A p.K77= | Silent (SNP) | VAF 59/226 reads (26%) | called by muse, mutect2, varscan2
- DGAT2 | c.240C>T p.F80= | Silent (SNP) | VAF 24/209 reads (11%) | catalogued as rs1565316229, COSV99930065; called by muse, mutect2, varscan2
- DGKI | c.2409C>T p.S803= | Silent (SNP) | VAF 27/244 reads (11%) | catalogued as COSV99936942; called by muse, mutect2, varscan2
- DHX35 | c.1182T>G p.G394= | Silent (SNP) | VAF 90/237 reads (38%) | called by muse, mutect2, varscan2
- DISP1 | c.2796C>T p.L932= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs760110946; called by muse, mutect2, varscan2
- DLEC1 | c.3000C>T p.T1000= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as COSV100343586; called by muse, varscan2
- DMGDH | c.216G>A p.G72= | Silent (SNP) | VAF 38/265 reads (14%) | catalogued as COSV54862251; called by muse, mutect2, varscan2
- DNAH14 | c.5187G>A p.K1729= (on ENST00000445597; = p.K2134= on NM_001367479.1) | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2
- DNAH5 | c.10230G>A p.T3410= | Silent (SNP) | VAF 80/302 reads (26%) | catalogued as rs765000004, COSV54201418; called by muse, mutect2, varscan2
- DNAH9 | c.10903C>T p.L3635= | Silent (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- DNASE2B | c.51C>T p.L17= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- DNASE2B | c.591C>T p.S197= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- DPH2 | c.1353C>T p.F451= | Silent (SNP) | VAF 41/234 reads (18%) | catalogued as rs769917567, COSV99356596; called by muse, mutect2, varscan2
- DSTYK | c.1840C>A p.R614= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV100904756; called by muse, mutect2, varscan2
- DUOX2 | c.2991G>A p.K997= | Silent (SNP) | VAF 72/263 reads (27%) | called by muse, mutect2, varscan2
- DZIP1 | c.711G>A p.E237= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- EDA2R | c.558G>A p.E186= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs777771019; called by muse, mutect2
- EEF1A2 | c.228C>T p.S76= | Silent (SNP) | VAF 48/394 reads (12%) | catalogued as rs770506057, COSV99419693; called by muse, mutect2, varscan2
- EFCC1 | c.1533C>T p.S511= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs1376994100, COSV71402124; called by muse, mutect2, varscan2
- EGFLAM | c.2004G>A p.G668= | Silent (SNP) | VAF 25/206 reads (12%) | catalogued as COSV59292327; called by muse, mutect2, varscan2
- ELAPOR1 | c.2268C>T p.S756= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs751156341; called by muse, mutect2, varscan2
- EPB41L3 | c.1773G>A p.Q591= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- EPS8 | c.831G>A p.L277= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- F5 | c.6462C>T p.T2154= | Silent (SNP) | VAF 80/310 reads (26%) | called by muse, mutect2, varscan2
- FAM135B | c.4173C>T p.L1391= | Silent (SNP) | VAF 149/497 reads (30%) | called by muse, mutect2, varscan2
- FAM83F | c.1161C>T p.P387= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs776961253, COSV100329032, COSV61000237; called by muse, mutect2
- FAM83H | c.1449C>T p.F483= | Silent (SNP) | VAF 159/500 reads (32%) | catalogued as rs1293077907, COSV66353629; called by muse, mutect2, varscan2
- FAT2 | c.1008G>A p.R336= | Silent (SNP) | VAF 78/273 reads (29%) | called by muse, mutect2, varscan2
- FAT2 | c.594C>T p.P198= | Silent (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- FAT3 | c.3537C>T p.S1179= | Silent (SNP) | VAF 61/175 reads (35%) | called by muse, mutect2, varscan2
- FDPS | c.597C>T p.N199= | Silent (SNP) | VAF 88/314 reads (28%) | called by muse, mutect2, varscan2
- FOXE1 | c.120G>A p.A40= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs760222007; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1209C>T p.I403= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- GBP7 | c.180G>A p.G60= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- GDPD4 | c.573G>A p.K191= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV60021989; called by muse, mutect2
- GON4L | c.4167C>T p.T1389= | Silent (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- GPC2 | c.525C>T p.F175= | Silent (SNP) | VAF 178/551 reads (32%) | called by muse, mutect2, varscan2
- GPR27 | c.117C>T p.F39= | Silent (SNP) | VAF 34/237 reads (14%) | called by muse, mutect2, varscan2
- GREB1 | c.2451C>T p.S817= | Silent (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2, varscan2
- GRIK2 | c.22C>T p.L8= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- GRIK2 | c.2595G>A p.L865= | Silent (SNP) | VAF 30/204 reads (15%) | called by muse, mutect2, varscan2
- GRIN2A | c.3018G>A p.A1006= | Silent (SNP) | VAF 111/293 reads (38%) | catalogued as rs761132463, COSV58037726; called by muse, mutect2, varscan2
- GRM3 | c.822C>T p.L274= | Silent (SNP) | VAF 105/315 reads (33%) | catalogued as rs374839602; called by muse, mutect2, varscan2
- GUCY1A2 | c.2184G>A p.R728= | Silent (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- HBG1 | c.297G>A p.V99= | Silent (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- HCN1 | c.2010G>A p.A670= | Silent (SNP) | VAF 125/439 reads (28%) | catalogued as rs755532252, COSV57496207, COSV57511213; called by muse, mutect2, varscan2
- HECW1 | c.144C>T p.F48= | Silent (SNP) | VAF 118/419 reads (28%) | called by muse, mutect2, varscan2
- HLF | c.567C>T p.G189= | Silent (SNP) | VAF 67/823 reads (8%) | called by muse, mutect2
- HNF4A | c.1419T>A p.V473= | Silent (SNP) | VAF 108/311 reads (35%) | called by muse, mutect2, varscan2
- HOOK1 | c.1233G>A p.K411= | Silent (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- HSH2D | c.609C>T p.L203= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as rs757873136; called by muse, mutect2, varscan2
- HTR1A | c.1008C>T p.A336= | Silent (SNP) | VAF 82/273 reads (30%) | catalogued as rs1431188133; called by muse, mutect2, varscan2
- IDH2 | c.642A>C p.A214= | Silent (SNP) | VAF 255/657 reads (39%) | called by muse, mutect2, varscan2
- IGFL3 | c.186C>T p.S62= | Silent (SNP) | VAF 78/244 reads (32%) | called by muse, mutect2, varscan2
- IGFN1 | c.2847C>T p.L949= (on ENST00000295591 / NM_001367841.1; = p.L3406= on NM_001164586.2) | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1167049613, COSV55181532; called by muse, mutect2
- IGSF10 | c.5589C>T p.P1863= | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as rs963050918; called by muse, mutect2, varscan2
- IGSF9B | c.3228C>T p.L1076= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV58072819; called by muse, mutect2, varscan2
- IL17RA | c.540C>T p.F180= | Silent (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- ILF2 | c.840C>T p.F280= | Silent (SNP) | VAF 56/189 reads (30%) | called by muse, mutect2, varscan2
- INSR | c.2934C>T p.F978= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as COSV100252726; called by muse, mutect2, varscan2
- IQCE | c.1626G>A p.L542= | Silent (SNP) | VAF 31/275 reads (11%) | catalogued as rs1209445850; called by muse, mutect2, varscan2
- IRF5 | c.12C>T p.S4= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- ITGAL | c.2184C>T p.S728= | Silent (SNP) | VAF 40/210 reads (19%) | called by muse, varscan2
- KCNAB2 | c.124C>T p.L42= | Silent (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1233G>A p.P411= (on ENST00000359125 / NM_172107.4; = p.P401= on NM_004518.6) | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as rs757596960, COSV60556212; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM4D | c.1269C>T p.V423= | Silent (SNP) | VAF 132/438 reads (30%) | called by muse, mutect2, varscan2
- KDM4E | c.525C>T p.P175= | Silent (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- KIF5C | c.147C>T p.F49= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as rs771597140, COSV70532920; called by muse, mutect2, varscan2
- KMT2D | c.5502C>T p.S1834= | Silent (SNP) | VAF 41/200 reads (21%) | called by muse, mutect2, varscan2
- KRR1 | c.99C>T p.L33= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs776874637; called by muse, mutect2, varscan2
- KRTAP23-1 | c.153C>T p.F51= | Silent (SNP) | VAF 113/484 reads (23%) | catalogued as COSV61935729; called by muse, mutect2, varscan2
- LILRB2 | c.945C>T p.I315= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV58744980; called by muse, mutect2
- LINGO4 | c.1098C>T p.L366= | Silent (SNP) | VAF 36/342 reads (11%) | called by muse, mutect2, varscan2
- LPA | c.1068C>T p.S356= | Silent (SNP) | VAF 26/1293 reads (2%) | catalogued as rs763945626; called by muse, mutect2
- LRP1B | c.6609T>G p.S2203= | Silent (SNP) | VAF 46/196 reads (23%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.4746C>T p.L1582= | Silent (SNP) | VAF 30/402 reads (7%) | called by muse, mutect2
- LSAMP | c.489C>T p.I163= | Silent (SNP) | VAF 98/309 reads (32%) | called by muse, mutect2, varscan2
- LSM10 | c.228C>T p.G76= | Silent (SNP) | VAF 48/529 reads (9%) | called by muse, mutect2
- MADD | c.1146C>T p.F382= | Silent (SNP) | VAF 74/285 reads (26%) | catalogued as rs1168628095; called by muse, mutect2, varscan2
- MAP3K9 | c.702G>A p.G234= | Silent (SNP) | VAF 37/218 reads (17%) | catalogued as rs1454621812; called by muse, mutect2, varscan2
273 further variants in this file (0 protein-altering or splice-affecting, 147 silent, 126 other) are not listed here.
